Somatic mutation profile of tumor specimen CPT000415 (aliquot CPT000415-0015) from CPTAC case 05BR051, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.6 years (23,603 days).
Specimen CPT000415: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05fabc4d-edee-4d21-93eb-d805c31020ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000409 (Blood Derived Normal), aliquot CPT000409-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/632c76af-831c-43dc-bec0-d8b01bd15af1

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Intron 4, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 1, Splice Site 1, Splice Region 1, 3'UTR 1, 5'Flank 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 104/200 reads (52%) | hotspot (GDC flag); catalogued as CD951866, COSV52713084, COSV52728511, COSV53025106, COSV53864205; called by muse, mutect2, varscan2
- ASB7 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV58404404; called by muse, mutect2, varscan2
- B3GALT2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.068); catalogued as rs201702090, COSV66463858; called by muse, mutect2, varscan2
- C19orf47 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as rs1350283422; called by muse, mutect2, varscan2
- CAPN2 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 87/450 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143885626; called by muse, mutect2, varscan2
- CDC42BPB | c.2456C>T p.A819V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs377033153, COSV100775525; called by muse, mutect2, varscan2
- CNTNAP4 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199840526; called by muse, mutect2, varscan2
- GOLGA8G | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1356706190; called by mutect2, varscan2
- GRM3 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750079420, COSV64468260; called by muse, mutect2, varscan2
- ISLR | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT tolerated (0.9); PolyPhen benign (0.039); catalogued as COSV51432826; called by muse, mutect2, varscan2
- NHP2 | c.339C>T p.D113= | Splice Region (SNP) | VAF 152/228 reads (67%) | catalogued as rs561948156; called by muse, mutect2, varscan2
- PCDH11X | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 67/346 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1451020542, COSV100016238; called by muse, mutect2, varscan2
- PCDH15 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 59/250 reads (24%) | catalogued as rs1421575182, COSV57318786; called by muse, varscan2
- PCDHA1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 122/474 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as COSV65377087; called by muse, mutect2, varscan2
- PHC1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 70/110 reads (64%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.777); catalogued as COSV70418592; called by muse, mutect2, varscan2
- PRDM13 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs368251086, COSV65030836; called by muse, mutect2, varscan2
- SEC61B | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as rs748304714; called by muse, mutect2, varscan2
- SLC13A4 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770016739, COSV62460022; called by muse, mutect2, varscan2
- SLC16A6 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782713311, COSV59179569; called by mutect2, varscan2
- SLC24A1 | c.2752G>A p.V918M | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs775935542, COSV56051998; called by muse, mutect2, varscan2
- TNXB | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs202076639, COSV64475334; called by muse, varscan2
- B4GALNT3 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5R2 | c.71A>C p.E24A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- CREB3L4 | c.743+2T>C p.X248_splice | Splice Site (SNP) | VAF 13/425 reads (3%) | called by muse, mutect2
- GUCY1A1 | c.1853T>C p.V618A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- KCNN2 | c.1350A>C p.K450N (on ENST00000264773; = p.K662N on NM_021614.4) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- LSAMP | c.121A>T p.I41F | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- NIPBL | c.7000A>T p.M2334L | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NOXRED1 | c.671A>G p.Y224C | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.087); called by muse, varscan2
- PIR | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRC2B | c.5419G>T p.G1807W | Missense Mutation (SNP) | VAF 117/229 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PTMA | c.163_168delinsCTTC p.E55Lfs*16 (on ENST00000341369 / NM_001099285.2; = p.E54Lfs*16 on NM_002823.5) | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | called by pindel, varscan2*
- REG3A | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by mutect2, varscan2
- SP100 | c.2645T>C p.I882T | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SYNE1 | c.20737del p.R6913Afs*8 (on ENST00000367255 / NM_182961.4; = p.R6842Afs*8 on NM_033071.3) | Frame Shift Del (DEL) | VAF 30/199 reads (15%) | called by mutect2, varscan2
- TRAJ47 | c.38C>G p.T13S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF528 | c.728G>C p.C243S | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADSS1 | c.834C>T p.G278= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs757835976, COSV58273335; called by muse, mutect2, varscan2
- AKAP4 | c.2214C>T p.G738= | Silent (SNP) | VAF 58/249 reads (23%) | called by muse, mutect2, varscan2
- DCLK2 | c.738C>T p.C246= | Silent (SNP) | VAF 29/97 reads (30%) | called by muse, varscan2
- HKDC1 | c.1218C>T p.L406= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as COSV63578163; called by muse, mutect2
- MC3R | c.519C>T p.G173= | Silent (SNP) | VAF 156/414 reads (38%) | catalogued as COSV54765103; called by muse, mutect2, varscan2
- PLXNA3 | c.2031C>A p.V677= | Silent (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- RPTN | c.120G>A p.E40= | Silent (SNP) | VAF 40/251 reads (16%) | called by muse, mutect2, varscan2
- SKOR2 | c.2310C>T p.D770= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs887550919, COSV68550316; called by muse, mutect2, varscan2
- SLC6A13 | c.1533C>T p.S511= | Silent (SNP) | VAF 79/177 reads (45%) | catalogued as COSV58256394; called by muse, mutect2, varscan2
- TRPM1 | c.4650A>G p.S1550= | Silent (SNP) | VAF 249/411 reads (61%) | called by muse, mutect2, varscan2
- ZNF517 | c.936C>T p.S312= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs199630389, COSV100743667, COSV63465466; called by muse, mutect2, varscan2
- ADARB2 | c.1682+17C>A | Intron (SNP) | VAF 195/492 reads (40%) | called by muse, mutect2, varscan2
- AGAP2 | chr12:57742038 C>A | 5'Flank (SNP) | VAF 80/1628 reads (5%) | called by muse, mutect2
- NCAPD2 | c.*177T>A | 3'UTR (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- PCNX1 | c.4577+1317A>G | Intron (SNP) | VAF 14/99 reads (14%) | catalogued as rs779661731; called by muse, mutect2, varscan2
- PTGES3 | c.2+19C>T | Intron (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- RAB34 | c.-267G>A | 5'UTR (SNP) | VAF 54/101 reads (53%) | called by muse, varscan2
- RPS24 | c.279+43T>A | Intron (SNP) | VAF 63/230 reads (27%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580968 G>A | 3'Flank (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
